Somatic mutation profile of tumor specimen TCGA-58-A46L-01A (aliquot TCGA-58-A46L-01A-11D-A24D-08) from TCGA case TCGA-58-A46L, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.1 years (26,685 days).
Specimen TCGA-58-A46L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9292f47c-e1be-495f-840c-67713b228f43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-A46L-10A (Blood Derived Normal), aliquot TCGA-58-A46L-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc1ad5f-d03b-496d-8a87-cb44add8df78

The open-access MAF lists 233 somatic variants for this specimen: 184 protein-altering or splice-affecting, 42 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 42, Nonsense Mutation 10, Splice Site 6, RNA 3, Intron 3, Splice Region 2, Frame Shift Del 2, Translation Start Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4169dup p.L1390Ffs*13 | Frame Shift Ins (INS) | VAF 11/65 reads (17%) | catalogued as rs80359433; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99288354; called by muse, mutect2, varscan2
- ABCA8 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.176); catalogued as COSV99285427; called by muse, mutect2, varscan2
- ADCY8 | c.2141C>A p.S714* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV99651644; called by muse, mutect2, varscan2
- ADGRB3 | c.1795A>G p.T599A | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV101000291, COSV101000292; called by muse, mutect2, varscan2
- AFF4 | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54792357, COSV99534808; called by muse, mutect2, varscan2
- AGPS | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931203; called by muse, mutect2, varscan2
- AHCTF1 | c.5599G>C p.E1867Q (on ENST00000366508; = p.E1841Q on NM_015446.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV100403473; called by mutect2, varscan2
- ALS2 | c.4626G>T p.K1542N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV99969117; called by muse, mutect2, varscan2
- ANK2 | c.11552C>G p.S3851C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100000890; called by muse, mutect2, varscan2
- ANKRD12 | c.3989G>A p.S1330N | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs139801157; called by muse, mutect2, varscan2
- ANO8 | c.2893C>G p.R965G | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99344322; called by muse, mutect2, varscan2
- APBB1IP | c.741G>A p.W247* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100770887; called by muse, mutect2, varscan2
- APOBEC1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV99981056, COSV99981091; called by muse, mutect2, varscan2
- ARFGEF3 | c.3955G>T p.V1319F | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99293043; called by muse, mutect2, varscan2
- ASB5 | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 30/73 reads (41%) | catalogued as COSV99641527; called by muse, mutect2, varscan2
- B3GAT2 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as COSV100016813; called by muse, mutect2, varscan2
- BCL6B | c.1220C>A p.T407N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99546563; called by muse, mutect2, varscan2
- BFSP2 | c.730-1G>T p.X244_splice | Splice Site (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100183683; called by muse, mutect2, varscan2
- BRINP1 | c.2108T>C p.I703T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99775089; called by muse, mutect2, varscan2
- BRMS1L | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99396614; called by muse, mutect2
- CACNA1C | c.4967G>A p.R1656H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59715522, COSV59779817; called by muse, mutect2, varscan2
- CARNS1 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs774158458, COSV57049803; called by muse, mutect2, varscan2
- CCDC150 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99776764; called by muse, mutect2, varscan2
- CCDC151 | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100710500, COSV62698444; called by muse, mutect2, varscan2
- CCDC74B | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.862); catalogued as COSV100134348; called by muse, mutect2, varscan2
- CD1B | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 303/430 reads (70%) | catalogued as COSV100939214; called by muse, mutect2, varscan2
- CDH10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs113887214, COSV100050954, COSV52573520; called by muse, mutect2, varscan2
- CDHR3 | c.1983G>T p.R661S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100488191, COSV58416593; called by muse, mutect2, varscan2
- CEP170 | c.1294G>T p.G432W | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100316833; called by muse, mutect2, varscan2
- CERS3 | c.289-1G>T p.X97_splice | Splice Site (SNP) | VAF 28/48 reads (58%) | catalogued as COSV99431765; called by muse, mutect2, varscan2
- CFAP36 | c.294A>C p.Q98H | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100170875; called by muse, mutect2, varscan2
- CFAP69 | c.1959G>T p.K653N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV100289998; called by muse, mutect2, varscan2
- CLVS2 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV51564287; called by muse, mutect2, varscan2
- CLVS2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as COSV51560549; called by muse, mutect2, varscan2
- COG4 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100091608; called by muse, mutect2, varscan2
- CPED1 | c.453T>A p.D151E | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100120454; called by muse, mutect2, varscan2
- CPED1 | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs753255831, COSV100120455; called by muse, mutect2, varscan2
- CRADD | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.557); catalogued as COSV100257515; called by muse, mutect2, varscan2
- CSMD3 | c.4610G>C p.G1537A (on ENST00000297405 / NM_001363185.1; = p.G1433A on NM_052900.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99831044; called by muse, mutect2, varscan2
- CSMD3 | c.4609G>C p.G1537R (on ENST00000297405 / NM_001363185.1; = p.G1433R on NM_052900.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99831046; called by muse, mutect2, varscan2
- DCSTAMP | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs56239450, COSV99886399; called by muse, mutect2, varscan2
- DDX25 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99699826; called by muse, mutect2, varscan2
- DIAPH1 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526314; called by muse, mutect2, varscan2
- DLK2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99767049; called by muse, mutect2, varscan2
- DNAAF2 | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs562712293, COSV100023927; called by muse, mutect2, varscan2
- DNAJB13 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV100334479; called by muse, mutect2, varscan2
- DNAJB13 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100334481; called by muse, mutect2, varscan2
- EDEM2 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100993713; called by muse, mutect2, varscan2
- EEF2K | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1249576175, COSV99532951; called by muse, mutect2, varscan2
- EIF2AK1 | c.629A>T p.K210M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99551789; called by muse, mutect2, varscan2
- EPHB6 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs573448355, COSV101235964; called by muse, mutect2, varscan2
- ESR2 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs755401425, COSV99963047; called by muse, mutect2, varscan2
- ESYT2 | c.1051A>T p.I351F (on ENST00000613624; = p.I275F on NM_020728.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99276542; called by muse, mutect2, varscan2
- FMN2 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100144463; called by muse, mutect2, varscan2
- FOXP4 | c.1111C>A p.H371N (on ENST00000307972 / NM_001012426.1; = p.H370N on NM_138457.3) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100332595; called by muse, mutect2, varscan2
- FREM1 | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV100772188; called by muse, mutect2, varscan2
- FRY | c.2879G>A p.G960D | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100969052; called by muse, mutect2, varscan2
- GNAI1 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV100650454; called by muse, mutect2, varscan2
- GNE | c.604A>C p.M202L (on ENST00000396594 / NM_001128227.3; = p.M171L on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.175); catalogued as CM023830, COSV100929934; called by muse, mutect2, varscan2
- GPR65 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99965997; called by muse, mutect2, varscan2
- GRM6 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs372252788; called by muse, mutect2, varscan2
- GRM8 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100282003; called by muse, mutect2, varscan2
- H2BW1 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV99475029; called by muse, mutect2, varscan2
- HAT1 | c.911A>T p.K304I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99907891; called by muse, mutect2
- HERC1 | c.11272G>C p.D3758H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101496499; called by muse, varscan2
- HGF | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV99736444; called by muse, mutect2, varscan2
- ICE2 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV99831445; called by muse, mutect2, varscan2
- IGKV2D-29 | c.180G>C p.W60C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101534372; called by muse, mutect2, varscan2
- IGKV3-20 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs768320122; called by muse, mutect2, varscan2
- IGSF11 | c.329C>A p.T110N (on ENST00000393775 / NM_001015887.3; = p.T109N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100677210; called by muse, mutect2, varscan2
- IPO11 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100320543; called by muse, mutect2, varscan2
- IPO11 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV100320545; called by muse, mutect2, varscan2
- IQGAP1 | c.4063G>T p.A1355S | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99184943; called by muse, mutect2, varscan2
- IQUB | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.358); catalogued as COSV100226980; called by muse, mutect2
- IRAK3 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54166340, COSV99705864; called by muse, mutect2, varscan2
- IREB2 | c.1237A>T p.K413* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99359281; called by muse, mutect2, varscan2
- ITGAX | c.2050G>C p.G684R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99191594; called by muse, mutect2, varscan2
- ITGAX | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99191595; called by muse, mutect2, varscan2
- JAG2 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100078132; called by muse, mutect2, varscan2
- KASH5 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs983624442, COSV71358576; called by muse, mutect2, varscan2
- KDR | c.1093T>G p.Y365D | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99817289; called by muse, mutect2, varscan2
- KLHL1 | c.1624C>A p.H542N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100917142; called by muse, mutect2
- KLHL1 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs986186439, COSV100917143; called by muse, mutect2, varscan2
- KLHL24 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV99664848; called by muse, mutect2, varscan2
- LAMA2 | c.4187C>A p.P1396Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs539352717, COSV101370343, COSV70356386; called by muse, mutect2, varscan2
- LRRC66 | c.2417C>A p.P806H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751387667, COSV100602921; called by muse, mutect2, varscan2
- LRRC7 | c.508G>A p.D170N (on ENST00000651989 / NM_001370785.2; = p.D137N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99225841; called by muse, mutect2, varscan2
- LTBP4 | c.3853T>C p.Y1285H (on ENST00000308370 / NM_001042544.1; = p.Y1248H on NM_003573.2) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99184817; called by muse, mutect2, varscan2
- MASTL | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs28941470, CM032683, COSV100668868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBL2 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 233/396 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100906312, COSV100906374; called by muse, mutect2, varscan2
- MIDEAS | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV54099785, COSV99678775; called by muse, mutect2, varscan2
- MIER3 | c.1150C>G p.Q384E (on ENST00000381199 / NM_001297599.2; = p.Q383E on NM_152622.4) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.027); catalogued as COSV101167566; called by muse, mutect2, varscan2
- MIOS | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100402667; called by muse, mutect2, varscan2
- MLLT10 | c.2776A>G p.M926V (on ENST00000307729 / NM_001195626.3; = p.M942V on NM_004641.3) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758174027, COSV100307878; called by muse, mutect2, varscan2
- MMP26 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100332044; called by muse, mutect2, varscan2
- MPP7 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747368673, COSV100517233; called by muse, mutect2, varscan2
- NFATC4 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51601443, COSV99145176; called by muse, mutect2, varscan2
- NME3 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1030732407, COSV51598885, COSV99167837; called by muse, mutect2, varscan2
- NRCAM | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.031); catalogued as rs757035974, COSV100694550, COSV100695833; called by muse, mutect2, varscan2
- NUP88 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99851589; called by muse, mutect2, varscan2
- OBSCN | c.10870C>G p.L3624V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV52853593; called by muse, mutect2, varscan2
- OR10G3 | c.318C>G p.H106Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100336081; called by muse, mutect2, varscan2
- OR1B1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs547773297, COSV100506448; called by muse, mutect2, varscan2
- OR1C1 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs535746640, COSV101376213; called by muse, mutect2, varscan2
- OR52E6 | c.835A>C p.N279H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100259264; called by muse, mutect2, varscan2
- OR5F1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99558540; called by muse, mutect2, varscan2
- OR5K4 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721331; called by muse, mutect2, varscan2
- OR8G1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV100422357; called by muse, mutect2, varscan2
- PAQR9 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61418672; called by muse, mutect2, varscan2
- PCDH18 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs150085543; called by muse, mutect2, varscan2
- PCDHA13 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV99165664; called by muse, mutect2, varscan2
- PCDHA13 | c.2291C>G p.P764R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as COSV56498016, COSV99165666; called by muse, mutect2, varscan2
- PCDHA8 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100969361, COSV65328168; called by muse, mutect2, varscan2
- PDE10A | c.1741C>G p.P581A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100604933; called by muse, mutect2, varscan2
- PDE4B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV100303091; called by muse, mutect2, varscan2
- PGBD1 | c.396G>A p.Q132= | Splice Region (SNP) | VAF 53/110 reads (48%) | catalogued as COSV99460027; called by muse, mutect2, varscan2
- PHEX | c.1027G>T p.V343F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.915); catalogued as COSV101039549, COSV65078293; called by muse, mutect2, varscan2
- PLA2G4A | c.2159G>T p.R720I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs559871981, COSV100820496; called by muse, mutect2, varscan2
- PLXNA4 | c.1807G>T p.G603W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100322915; called by muse, mutect2, varscan2
- POLE | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs115225325, COSV100266006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCZ | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057643; called by muse, mutect2, varscan2
- PTCRA | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100485730; called by muse, mutect2, varscan2
- PTPN3 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs554596041, COSV99355612; called by muse, mutect2, varscan2
- PTPRB | c.5195G>T p.R1732L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99716851; called by muse, mutect2, varscan2
- PUS7L | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100786514; called by muse, mutect2, varscan2
- RASGEF1A | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs764801376, COSV100988655, COSV100988688; called by muse, mutect2, varscan2
- RAVER2 | c.1892G>T p.C631F (on ENST00000294428 / NM_001366165.1; = p.C618F on NM_018211.4) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.084); catalogued as COSV53804873, COSV99605034; called by muse, mutect2, varscan2
- RBM8A | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100355260; called by muse, mutect2, varscan2
- ROBO4 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs971468314, COSV100127466; called by muse, mutect2, varscan2
- RRP36 | c.620A>T p.H207L | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); catalogued as COSV99763686; called by muse, mutect2, varscan2
- RYR1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 136/229 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093209; called by muse, mutect2, varscan2
- SALL3 | c.2522C>A p.A841D | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101609974; called by muse, mutect2, varscan2
- SCLT1 | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99827906; called by muse, mutect2, varscan2
- SELENOP | c.922A>T p.I308L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as COSV100736794; called by muse, mutect2, varscan2
- SEMA3A | c.2269A>T p.R757* | Nonsense Mutation (SNP) | VAF 44/189 reads (23%) | catalogued as COSV99546112; called by muse, mutect2, varscan2
- SETD1A | c.4306G>T p.D1436Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99352764; called by muse, mutect2, varscan2
- SHOX2 | c.795T>G p.H265Q (on ENST00000441443 / NM_006884.3; = p.H289Q on NM_003030.4) | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV101273764; called by muse, mutect2, varscan2
- SLC12A8 | c.1741G>T p.V581F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100102176; called by muse, mutect2, varscan2
- SLC37A2 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV100017104; called by muse, mutect2, varscan2
- SLC4A2 | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100055161; called by muse, mutect2, varscan2
- SLC6A3 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99548104; called by muse, mutect2, varscan2
- SLC6A3 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54365723, COSV99548106; called by muse, mutect2, varscan2
- SLC9A3 | c.1432A>C p.K478Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99375872; called by muse, mutect2, varscan2
- SLCO2A1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60488523; called by muse, mutect2, varscan2
- SLIT2 | c.4349-2A>G p.X1450_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99882749; called by muse, mutect2, varscan2
- SNED1 | c.2340C>A p.S780R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100122517; called by muse, mutect2, varscan2
- SPACA7 | c.445+2T>C p.X149_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52104633; called by muse, mutect2, varscan2
- SPACA7 | c.523+2T>A p.X175_splice | Splice Site (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99366547; called by muse, mutect2, varscan2
- SPATA31E1 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100350257; called by muse, mutect2, varscan2
- SPTB | c.5986G>C p.E1996Q | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV101072045; called by muse, mutect2, varscan2
- SYTL2 | c.2001A>T p.P667= (on ENST00000528231 / NM_001162951.2; = p.P643= on NM_032943.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100314029; called by muse, mutect2, varscan2
- TAS2R1 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.294); catalogued as rs1254587468, COSV101225737; called by muse, mutect2, varscan2
- TBC1D22A | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100452877; called by muse, mutect2, varscan2
- TCOF1 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV100077210; called by muse, mutect2, varscan2
- TENM1 | c.3868G>A p.D1290N | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV100949700; called by muse, mutect2, varscan2
- TLE3 | c.1902G>T p.W634C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100450259, COSV58169118; called by muse, mutect2, varscan2
- TLE3 | c.1901G>T p.W634L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100450262; called by muse, mutect2, varscan2
- TLR4 | c.917G>T p.C306F (on ENST00000355622 / NM_138554.5; = p.C266F on NM_003266.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100790631; called by muse, mutect2, varscan2
- TNFSF14 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV99838422; called by muse, mutect2, varscan2
- TNK2 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766460416, COSV100361176; called by muse, mutect2, varscan2
- TNN | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 81/130 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV53430609, COSV53433654, COSV99511160; called by muse, mutect2, varscan2
- TPR | c.3506A>T p.K1169M | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100823811, COSV66599440; called by muse, mutect2, varscan2
- TRIOBP | c.6803G>T p.G2268V (on ENST00000644935 / NM_001039141.3; = p.G555V on NM_007032.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100730785; called by muse, mutect2, varscan2
- TRIP12 | c.3810A>T p.L1270F | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV99389879; called by muse, mutect2, varscan2
- TTN | c.24457G>T p.G8153* (on ENST00000591111; = p.G7226* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 62/128 reads (48%) | catalogued as COSV100605013; called by muse, mutect2, varscan2
- TTN | c.14705C>A p.S4902Y (on ENST00000591111; = p.S3975Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/279 reads (47%) | PolyPhen benign (0.173); catalogued as COSV100605015; called by muse, mutect2, varscan2
- TTN | c.11798T>G p.V3933G (on ENST00000591111; = p.V3887G on NM_003319.4) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV100605017; called by muse, mutect2, varscan2
- TTN | c.10463C>A p.P3488Q (on ENST00000591111; = p.P3442Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100605019; called by muse, mutect2, varscan2
- TUBA3C | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101262777; called by muse, mutect2, varscan2
- UMOD | c.1695C>A p.H565Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56778367; called by muse, mutect2, varscan2
- URB2 | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.293); catalogued as COSV51058058; called by muse, mutect2, varscan2
- VCAN | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99425355; called by muse, mutect2, varscan2
- VWF | c.3817A>G p.S1273G | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV99778691; called by muse, mutect2, varscan2
- WASHC5 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100572745; called by muse, mutect2, varscan2
- ZDHHC14 | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100702143; called by muse, mutect2, varscan2
- ZFAND4 | c.1339G>T p.G447* | Nonsense Mutation (SNP) | VAF 52/161 reads (32%) | catalogued as COSV100762943; called by muse, mutect2, varscan2
- ZFYVE9 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as COSV99819752; called by muse, mutect2, varscan2
- ZNF385D | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55766274, COSV99874198; called by muse, mutect2, varscan2
- ZNF804B | c.684C>A p.H228Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.726); catalogued as COSV100303016; called by muse, mutect2, varscan2
- ZNF804B | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV60819221; called by muse, mutect2, varscan2
- ZSWIM1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99666392; called by muse, mutect2, varscan2
- CLDN12 | c.178_179delinsT p.R60Cfs*9 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | called by pindel, varscan2*
- TP53 | c.108_133del p.S37Vfs*6 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel
- ABCA10 | c.84T>A p.L28= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99288356; called by muse, mutect2, varscan2
- ACAP3 | c.966G>T p.P322= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100686268; called by muse, mutect2, varscan2
- ARHGAP22 | c.123G>T p.A41= | Silent (SNP) | VAF 88/219 reads (40%) | catalogued as COSV99984981; called by muse, mutect2, varscan2
- CAMSAP3 | c.1284C>T p.R428= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99350334; called by muse, mutect2, varscan2
- CLDN18 | c.774C>T p.H258= | Silent (SNP) | VAF 44/177 reads (25%) | catalogued as rs750815878, COSV51736249, COSV99480745; called by muse, mutect2, varscan2
- COL13A1 | c.1590G>T p.G530= (on ENST00000398978 / NM_001130103.2; = p.G473= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100637413; called by muse, mutect2, varscan2
- COL4A6 | c.4644C>T p.T1548= | Silent (SNP) | VAF 62/110 reads (56%) | catalogued as rs776767877, COSV57860773; called by muse, mutect2, varscan2
- CPEB1 | c.258G>A p.T86= (on ENST00000617958; = p.T26= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/79 reads (57%) | catalogued as rs745469220, COSV101477622; called by muse, mutect2, varscan2
- DBF4B | c.816C>T p.S272= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100154435; called by muse, mutect2, varscan2
- DNAH2 | c.8916G>A p.R2972= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV101209171; called by muse, mutect2, varscan2
- FAT2 | c.1764C>T p.A588= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99942381; called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- GABRB2 | c.702C>G p.L234= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV50938318, COSV99195873; called by muse, mutect2, varscan2
- GAS2L2 | c.2508T>A p.G836= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs782114077; called by muse, mutect2, varscan2
- GLT6D1 | c.462G>T p.L154= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100874521; called by muse, mutect2, varscan2
- HCN1 | c.2166C>A p.P722= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100299708; called by muse, mutect2, varscan2
- IGFN1 | c.2340C>A p.I780= (on ENST00000295591 / NM_001367841.1; = p.I3237= on NM_001164586.2) | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99811870; called by muse, mutect2, varscan2
- KIF26B | c.1977C>T p.A659= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs377322149, COSV100831439; called by muse, mutect2, varscan2
- KIFC1 | c.1818G>A p.L606= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as COSV100996044; called by muse, mutect2, varscan2
- MRI1 | c.378C>T p.I126= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV99237378; called by muse, mutect2, varscan2
- MTR | c.2910G>T p.V970= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as COSV100855333; called by muse, mutect2, varscan2
- MUC16 | c.846G>T p.A282= | Silent (SNP) | VAF 91/232 reads (39%) | catalogued as COSV101199347; called by muse, mutect2, varscan2
- NUP205 | c.4036C>T p.L1346= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs773603397, COSV53666788, COSV53669033; called by muse, mutect2, varscan2
- OR13C3 | c.417A>T p.S139= | Silent (SNP) | VAF 127/216 reads (59%) | catalogued as COSV101053302, COSV66165815; called by muse, mutect2, varscan2
- PCDHA5 | c.2304C>G p.L768= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100972217; called by muse, mutect2, varscan2
- PHGDH | c.189C>T p.V63= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs372756781, COSV101025080; called by muse, mutect2, varscan2
- PRKRIP1 | c.420G>A p.L140= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs782445135, COSV100700338; called by muse, mutect2, varscan2
- RESF1 | c.1830A>G p.K610= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs979224697, COSV100440264; called by mutect2, varscan2
- SLC12A8 | c.502T>C p.L168= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100102178; called by muse, mutect2, varscan2
- SLC4A11 | c.114G>A p.Q38= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV101195930; called by muse, mutect2, varscan2
- SSTR1 | c.549G>T p.V183= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99942836; called by muse, mutect2, varscan2
- TAL2 | c.84C>T p.L28= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs765518830, COSV100482437; called by muse, mutect2, varscan2
- TEX13B | c.159C>T p.I53= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV100258323; called by muse, mutect2, varscan2
- TTC8 | c.1470C>A p.I490= (on ENST00000338104 / NM_001288781.1; = p.I474= on NM_144596.4) | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100581240; called by muse, mutect2
- TTN | c.14706C>G p.S4902= (on ENST00000591111; = p.S3975= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 131/278 reads (47%) | catalogued as COSV100605014; called by muse, mutect2, varscan2
- TTN | c.11799G>T p.V3933= (on ENST00000591111; = p.V3887= on NM_003319.4) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100605016; called by muse, mutect2, varscan2
- UBR4 | c.3795G>T p.V1265= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100920673; called by muse, mutect2, varscan2
- USF1 | c.273C>G p.T91= | Silent (SNP) | VAF 102/144 reads (71%) | catalogued as COSV99230951; called by muse, mutect2, varscan2
- VHL | c.243G>T p.P81= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99846129; called by muse, mutect2, varscan2
- WNT10B | c.63G>T p.A21= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99975883; called by muse, mutect2, varscan2
- ZACN | c.207C>T p.S69= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100135104; called by muse, mutect2, varscan2
- ZNF816 | c.96G>A p.E32= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV54410749; called by muse, mutect2, varscan2
- AC024940.1 | n.4499C>G | RNA (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- AP000769.5 | chr11:65498152 C>A | 5'Flank (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- C6orf223 | n.574G>T | RNA (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100350362, COSV100350395; called by muse, mutect2, varscan2
- CLCN5 | c.17-29055A>G | Intron (SNP) | VAF 72/137 reads (53%) | catalogued as rs782127597, COSV101067057; called by muse, mutect2, varscan2
- CTBP2 | c.58+12721G>T | Intron (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100456333; called by muse, mutect2, varscan2
- GRM8 | c.727+48354G>T | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100282000; called by muse, mutect2, varscan2
- SNORD115-6 | n.74C>A | RNA (SNP) | VAF 310/507 reads (61%) | called by muse, mutect2, varscan2
